Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3AZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3AZ-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name: [REDACTED]	Service: [REDACTED]	Accession #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Received: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	Reported: [REDACTED]
HCN: [REDACTED]		
Ordering MD: [REDACTED]		
Copy To: [REDACTED]		

UUID: EASD2C1C-703B-46BE-8B16-C40CE4BA0B46

Specimen(s) Received

1. Uterus: cervix, bilateral tubes and ovaries

Diagnosis

1. Uterus, cervix, bilateral tubes and ovaries:

Uterus:

MIXED SEROUS AND ENDOMETRIOID CARCINOMA OF ENDOMETRIUM:

- serous component greater than 50%
- invasion into outer half of myometrial thickness
- extension into lower uterine segment, approaching but not into cervix
- lymphovascular space involvement present

Other:

- Leiomyomata

Ovaries:

- Negative for carcinoma

Fallopian tubes:

- Negative for carcinoma

Comment

The immunoprofile supports the diagnosis of serous carcinoma (p16, p53 positive; PR negative) in a portion of the tumour. A villoglandular component has the immunoprofile of an endometrioid carcinoma (ER positive, p53, p16 negative), supporting the impression of a true mixed serous and endometrioid carcinoma.

Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy
Lymph Node Sampling:	Not performed
Specimen Integrity:	Intact hysterectomy specimen
Tumor Size:	Greatest dimension: 2.8 cm
Histologic Type:	Serous adenocarcinoma

100-0-3
carcinoma, mixed endometrioid (838013)
and serous (844113) - code to highest
844113
Site: Endometrium C54.1 bx
11/13/11

Reviewed Initials:	KMT [Signature] 11/13/11	

[page 2 of 3]
Surgical Pathology Consultation Report

Histologic Grade: Not applicable
Myometrial Invasion: Present
Myometrial thickness: 9 mm
50% or greater myometrial invasion
Involvement of Cervix: Not involved
Extent of Involvement of Other Organs:
Right ovary not involved
Left ovary not involved
Right fallopian tube not involved
Left fallopian tube not involved
Lymph-Vascular Invasion: Present
TNM Descriptors: Not applicable
Primary Tumor (pT): pT1b (IB): Tumor invades more than one-half of the myometrium
Regional Lymph Nodes (pN): pNX: Regional lymph nodes cannot be assessed
Pelvic lymph nodes examined: 0
Pelvic lymph nodes involved: 0
Para-aortic lymph nodes examined: 0
Para-aortic lymph nodes involved: 0
Distant Metastasis (pM): Not applicable

Electronically verified by:

Clinical History endometrial ca

Gross Description

1. The specimen container is labeled with the patient's name and as "Uterus: Cervix, Bilateral Tubes and Ovaries". The specimen consists of a total hysterectomy specimen with attached bilateral salpingo-oophorectomy. The specimen has a fresh weight of 52.5 g. The uterus and cervix measures 7.0 cm SI x 4.5 cm ML x 3.3 cm AP. The cervix has a maximum diameter of 1.8 cm. The external os measures 0.4 cm and is oval. The right fallopian tube measures 5.7 cm length by 0.5 cm in diameter. The right ovary measures 1.3 x 1.4 x 0.3 cm. The left fallopian tube measures 5.0 cm in length by 0.6 in diameter. The left ovary measures 1.7 x 1.1 x 1.0 cm.

The uterine serosa is tan and smooth with a white nodule on the posterior aspect measuring 0.4 cm maximum dimension. The exocervix is pink tan and smooth with query of the anterior exocervix is partly missing. The endocervical canal measures 2.3 cm in length. The endometrial cavity demonstrates an ill-defined friable tan-brown tumor measuring 2.5 cm SI x 2.3 cm ML x 2.8 cm AP. The tumor measures 0.3 cm from the anterior serosal surface and 0.9 cm from the posterior serosal surface. The myometrium is tan and demonstrates a well circumscribed white nodule in the posterior aspect measuring 0.6 cm. Both fallopian tubes show fimbria. The outer surface of the ovaries is white tan and partly cerebriform. The cut surface of each ovary is tan and unremarkable. Within the paraovarian tissue there are two calcified nodules the largest measuring 0.2 cm. Tissue is stored frozen.

Representative sections:

- 1A longitudinal full thickness section of anterior exocervix to LUS
- 1B-1D full thickness partially transverse section of anterior tumor with endomyometrium
- 1E-1F longitudinal full thickness section of posterior exocervix to LUS [section bisected]
- 1G- 1H full thickness transverse section of posterior tumor with endomyometrium and serosal nodule [section bisected]
- 1I- 1J full thickness transverse section of posterior tumor with endomyometrium rectum section bisected]
- 1K right fallopian tube and fimbria
- 1L- 1M remainder of right fallopian tube serially sectioned from cornu to fimbrial end
- 1N representative sections of right ovary
- 1O left fallopian tube and fimbria
- 1P- 1Q remainder of left fallopian tube serially sectioned from cornua to fimbrial end
- 1R representative sections of left ovary
- 1S calcified nodules submitted for decalcification

[page 3 of 3]
Surgical Pathology Consultation Report

Source: NCI Genomic Data Commons file 95cf7952-f009-4a3f-a064-559007f46331 (TCGA-EO-A3AZ.EA5D2C1C-703B-46BE-8B16-C40CE4BA0B46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).